Somatic mutation profile of tumor specimen TCGA-SC-A6LP-01A (aliquot TCGA-SC-A6LP-01A-11D-A34C-32) from TCGA case TCGA-SC-A6LP, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 58.6 years (21,411 days).
Specimen TCGA-SC-A6LP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8cabe19-2caf-4697-ae77-8cf53c6e9b15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SC-A6LP-10A (Blood Derived Normal), aliquot TCGA-SC-A6LP-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b74c730-1808-48bc-9cee-d100053b9f7b

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 31/42 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UCHL5 | c.141-1G>T p.X47_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as COSV66486950; called by muse, mutect2, varscan2
- ABLIM3 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ACOT12 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADPGK | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- HECTD4 | c.10468G>A p.A3490T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IFI44L | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEGF8 | c.8009G>A p.W2670* (on ENST00000251268 / NM_001271938.2; = p.W2603* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 136/209 reads (65%) | called by muse, mutect2, varscan2
- NLRP7 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PPM1F | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 46/82 reads (56%) | called by muse, mutect2, varscan2
- RELN | c.10182-1G>A p.X3394_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- SETDB1 | c.3174dup p.R1059Sfs*13 | Frame Shift Ins (INS) | VAF 28/59 reads (47%) | called by mutect2, pindel, varscan2
- IFT74 | c.81G>T p.G27= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs892186414, COSV101197113; called by muse, mutect2, varscan2
- SLC9C2 | c.468C>T p.S156= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- TMEM144 | c.970C>T p.L324= | Silent (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
- TSPEAR | c.201C>T p.R67= | Silent (SNP) | VAF 71/131 reads (54%) | catalogued as rs782732230; called by muse, mutect2, varscan2
